Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7651, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7651-01A (Primary Tumor).

[page 1 of 2]
ORIGINAL REPORT

SPECIMEN:

A. Whipple's specimen (as per

CLINICAL HISTORY:

?ampullary tumor?

DIAGNOSIS:

A. WHIPPLE'S PROCEDURE:

- MODERATELY TO POORLY DIFFERENTIATED DUCTAL ADENOCARCINOMA OF THE PANCREAS.
- TUMOR LOCATED IN THE HEAD OF THE PANCREAS, 2.9 CM IN GREATEST DIMENSION.
- TUMOR INVADING DUODENUM FOCALLY REACHING DUODENAL MUCOSA.
- TUMOR INVADING COMMON BILE DUCT FOCALLY EXTENDING TO THE SURFACE EPITHELIUM.
- POSITIVE FOR LYMPH NODE METASTASES (3/8 NODES).
- VASCULAR INVASION IDENTIFIED.
- PERINEURAL INVASION IDENTIFIED.
- ALL RESECTION MARGINS NEGATIVE FOR TUMOR INVOLVEMENT.
- UNINVOLVED PANCREAS AND DUODENUM UNREMARKABLE.

SCANNED

GROSS DESCRIPTION:

A. The specimen is received fresh, subsequently placed into formalin, and consists of pyloric sphincter (6.0 cm circumference), duodenum (21.0 cm in length x 3.3 cm circumference), common bile duct (6.5 cm in length x 2.5 cm in maximum circumference), pancreas (8.0 cm in length x 4.0 cm x 2.5 cm), and some attached mesentery. Distal pancreatic margin is painted blue with anterior pancreas painted black and posterior pancreas surface painted orange. In the head of the pancreas, there is a poorly circumscribed effacement of normal pancreatic lobulation which is tan in color measuring 2.7 x 2.2 x 2.9 cm. The lesion is located 2.2 cm from the tip of the uncinate

FINAL

[page 2 of 2]
HISTOPATHOLOGY REPORT

Inquiry Number

Division Head

GROSS DESCRIPTION:

head, 1.2 cm from the distal pancreatic resection margin, seems to involve the biliary duct wall, and abuts the anterior surgical margin. The common bile duct appears proximally dilated to a diameter previously measured. Immediately distal to the dilatation, there is a stricture measuring a circumference of 1.4 cm. The serosal surface of the proximal duodenum is somewhat flattened with normal mucosal foldings commencing 8.0 cm from the pyloric sphincter. The ampulla is unremarkable. Sections are submitted as follows:

- A1. common bile duct margin
- A2. proximal margin of specimen at pyloric sphincter
- A3. distal specimen at duodenum
- A4-5. contiguous sections of pancreatic mass showing approximation with common bile duct and small bowel
- A6. representative section of tumor
- A7. uncinate margin
- A8. distal pancreatic margin
- A9. two lymph nodes bivalved, near uncinate head
- A10. three lymph nodes, one bivalve from distal pancreatic margin
- A11. two possible lymph nodes, near proximal distal pancreatic margin

MICROSCOPIC DESCRIPTION:

Sections of the pancreatic mass show a moderately to poorly differentiated ductal adenocarcinoma. The tumor cells form glandular structures or small nests with an infiltrating pattern. The tumor is located in the head of the pancreas and invades duodenum focally reaching duodenal mucosa. Tumor cells also focally invade common bile duct focally extending to the surface epithelium. Vascular invasion is identified. Perineural invasion is also seen. All resection margins are negative for tumor involvement. Eight lymph nodes are found and three of them show metastases with extranodal extension identified.

SCANNED

FINAL

Source: NCI Genomic Data Commons file 7bb08306-f5d7-48f9-bbb8-df0c4710af7b (TCGA-IB-7651.82E80295-8F27-45F4-9C47-323EAE67D009.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).